Somatic mutation profile of tumor specimen TARGET-40-PALZGU-01A (aliquot TARGET-40-PALZGU-01A-01D) from TARGET case TARGET-40-PALZGU, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 15.3 years (5,603 days).
Specimen TARGET-40-PALZGU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9ec3ada2-3e72-4e48-a473-d542b01f3054.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PALZGU-10A (Blood Derived Normal), aliquot TARGET-40-PALZGU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c44259dd-4638-4b2a-ad2b-4371ea63bc34

The open-access MAF lists 24 somatic variants for this specimen: 18 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Intron 3, Silent 2, Frame Shift Del 1, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEP19 | c.161A>G p.N54S | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.521); catalogued as rs181652552; called by muse, mutect2, varscan2
- CROT | c.656+1G>A p.X219_splice | Splice Site (SNP) | VAF 47/136 reads (35%) | catalogued as rs1176342735; called by muse, mutect2, varscan2
- ERBB4 | c.502C>T p.R168W | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs138433638, COSV53504288; called by muse, mutect2, varscan2
- FABP7 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 58/129 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as rs369011834; called by muse, mutect2, varscan2
- PCDHB5 | c.1519G>A p.A507T | Missense Mutation (SNP) | VAF 50/1890 reads (3%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); catalogued as rs782721729, COSV99169598; called by muse, mutect2
- PCSK1 | c.1693G>A p.G565S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100226966; called by muse, mutect2, varscan2
- PITPNM1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 310/898 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745995374; called by mutect2, varscan2
- RBM19 | c.745G>C p.A249P | Missense Mutation (SNP) | VAF 88/1594 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV55691552; called by muse, mutect2
- TAF3 | c.1768T>C p.F590L | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.137); catalogued as rs768354042; called by muse, mutect2, varscan2
- UGT2B28 | c.25C>T p.L9F | Missense Mutation (SNP) | VAF 103/234 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV59433222; called by muse, mutect2, varscan2
- ZFHX3 | c.3956G>T p.G1319V | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); catalogued as COSV99195373; called by muse, varscan2
- EIF3E | c.740A>C p.Q247P | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2
- KTI12 | c.111C>G p.D37E | Missense Mutation (SNP) | VAF 16/414 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.351); called by muse, mutect2
- MAMLD1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- PRMT6 | c.1116del p.M373Wfs*17 | Frame Shift Del (DEL) | VAF 25/60 reads (42%) | called by mutect2, pindel, varscan2
- SYNCRIP | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 11/285 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2
- TEX35 | c.337A>G p.K113E | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2
- TRMT2B | c.1393T>C p.C465R | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- JAM2 | c.285G>A p.R95= | Silent (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- OR2M2 | c.321G>T p.L107= | Silent (SNP) | VAF 92/280 reads (33%) | called by muse, mutect2, varscan2
- CD160 | c.538+110A>C | Intron (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2
- FKBP1B | c.85+132C>A | Intron (SNP) | VAF 4/21 reads (19%) | called by muse, varscan2
- PRKAR1A | c.709-38C>T | Intron (SNP) | VAF 12/16 reads (75%) | catalogued as rs536466197; called by muse, mutect2, varscan2
- ZNRD2 | chr11:65570416 G>A | 5'Flank (SNP) | VAF 37/175 reads (21%) | catalogued as rs1160591248; called by muse, mutect2, varscan2
